TCGA case TCGA-VS-A9U6 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98784bbe-e286-48df-838d-1a88040658bf

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 52 years; Vital status: Alive.

Diagnoses (4)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 52.3 years (19,109 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: M1; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 74 days; Days to treatment end: 105 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 74 days; Days to treatment end: 115 days; Treatment dose: 4,500 cGy; Treatment outcome: Stable Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 116 days; Days to treatment end: 129 days; Treatment dose: 2,600 cGy; Treatment outcome: Stable Disease; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 120 days; Days to treatment end: 129 days; Treatment dose: 900 cGy; Treatment outcome: Stable Disease; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,600 cGy; Treatment outcome: Stable Disease; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 4; Treatment outcome: Stable Disease; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 5,400 cGy; Treatment outcome: Stable Disease; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, large cell, nonkeratinizing, NOS), site: Connective, subcutaneous and other soft tissues of thorax. Age at diagnosis: 54.3 years (19,820 days); Days to diagnosis: 711 days (1.9 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, large cell, nonkeratinizing, NOS), site: Ovary. Age at diagnosis: 55.9 years (20,420 days); Days to diagnosis: 1,311 days (3.6 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Squamous cell carcinoma, large cell, nonkeratinizing, NOS), site: Liver. Age at diagnosis: 55.9 years (20,420 days); Days to diagnosis: 1,311 days (3.6 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 0 (preoperative): ECOG performance status: 1.
- Day 711 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to progression: 711 days (1.9 years); Evidence of progression type: Histologic Confirmation.
- Days to follow up: 1,213 days (3.3 years); Disease response: With Tumor.
- Day 1,311 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Ovary; Days to progression: 1,311 days (3.6 years).
- Day 1,311 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,311 days (3.6 years).
- Days to follow up: 1,320 days (3.6 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 156 cm; BMI: 27.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A9U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 60 mg.
  Slide TCGA-VS-A9U6-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VS-A9U6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A9U6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 1; Pregnancies count miscarriage: 1; Total pregnancy count: 2; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other).
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 4.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,320 days; disease-specific survival: no event (censored), 1,320 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 711 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A9U6-01A-11D-A42N-01): tumor purity 0.65, ploidy 2.21, whole-genome doublings 0.
